Surgical pathology report (de-identified scan), TCGA case TCGA-29-1710, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1710-01A (Primary Tumor).

[page 1 of 3]
Surg Path

TCGA-29-1710

CLINICAL HISTORY:

Abdominal pelvic swelling

GROSS EXAMINATION:

A. "Right gutter", received fresh. A 4.3 x 2 x 1.2 cm aggregate of fibromembranous tissue and nodular tissue fragments are received. Representative submitted as block A1.

B. "Lesser sac", received fresh and placed in formalin is a 5 x 3.9 x 2 cm aggregate of nodular, friable, yellow-tan fibromembranous tissue with focally solid and friable cut surfaces. Representative as block B1.

C. "Left gutter", received fresh. A 1.9 x 1.2 x 0.4 cm fragment of firm, white-tan fibrous tissue is bisected and entirely submitted as block C1.

D. "Left tube and ovary", received fresh. A 9.2 gram aggregate of tissue which is 4.5 x 3.2 x 1.2 cm. The surface is markedly disrupted and friable. There are fibrofatty adhesions. No definitive tubal structure is appreciated. A small area of calcification is noted at the periphery. Sectioning also demonstrates a 0.5 cm brown fluid filled cyst. Representative sections are submitted as blocks D1-D2.

E. "Right ovary and tube", received fresh. An 8.7 gram aggregate of tissue composed of a 2.8 x 2.4 x 1.2 cm ovary with a granular friable surface and attached fibrous tissue. No definitive tubal structure is appreciated. Sectioning through the ovary reveals a cystic and solid cut surface. Representative as blocks E1-E2.

F. "Uterus and cervix", received fresh. A 60 gram, 7 x 4.5 x 2.5 cm uterus is received. The serosa is tan-gray and focally granular. The ectocervix is white-tan and glistening with a central 0.5 cm os extending into a trabecular yellow endocervical canal with abundant adherent mucoid material. The endometrium is velvety, tan, 0.1 cm in thickness overlying a 1.3 cm myometrium with no nodules or masses.

BLOCK SUMMARY:

F1- anterior cervix.
F2- anterior endomyometrium.
F3- posterior cervix.
F4- posterior endomyometrium.
F5- serosal nodular adhesions.

G. "Cul de sac peritoneum", received fresh. A 3.6 x 1.7 x 0.8 cm fragment of firm, slightly nodular yellow-tan cauterized fibrofatty tissue is received. Representative sections are submitted in block G1.

H. "Segment of colon", received fresh. A 14 cm length of unoriented bowel is received with two stapled margins and attached mesenteric. The serosa is dusky red-brown with multiple dense nodular granular adhesions. The mucosa is velvety tan grossly unremarkable and the wall has a uniform thickness of 0.6 cm. Representative tangential margins of resection are submitted as block H1 and from full thickness bowel wall to include mesenteric nodule as block H2.

I. "Colon omentum", received fresh. An 11 cm length of unoriented bowel is received with adherent 16 x 13 x 5 cm of nodular, matted omental tissue. The bowel serosa is predominantly smooth and glistening and the mucosa is velvety tan and unremarkable. Sectioning through the matted omental tissue reveals

[page 2 of 3]
solid white cut surfaces. A representative section of bowel and matted omental tissue is submitted as block I1.

J. "Right diaphragm", received fresh. A 5.8 x 3.2 x 1.8 cm aggregate of red-tan fibromembranous tissue is received. There are multiple 0.1 cm to 0.2 cm embedded white nodules throughout the membranous tissue. Representative as block J1.

K. "Small bowel nodule", received fresh. A 2.2 x 0.7 x 0.4 cm aggregate of white-yellow nodular tissue is submitted in toto as block K1.

L. "Appendix", received fresh and placed in formalin is a 6.3 cm long, 0.5 cm in diameter segment of appendix with attached fat. The serosa is intact with focal adhesions and site nodularity. Sectioning reveals a patent lumen and uniform wall thickness of 0.4 cm. Representative submitted as block L1.

M. "Port a hepatic", received fresh. A 2.3 x 1.8 x 0.5 cm aggregate of cauterized yellow-tan fibromembranous tissue which is slightly nodular. Submitted in toto in block M1.

MICROSCOPIC EXAMINATION:
Microscopic examination is performed.

CGA-29-1710

PATHOLOGIC STAGE:
PROCEDURE: HYSTERECTOMY & OOPHORECTOMY AND EXTENSIVE STAGING PROCEDURE

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX (FOR OVARY)

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

****REVISED DIAGNOSIS**:**
CORRECTION OF LETTER CODE
THERE IS NO CHANGE IN DIAGNOSIS

DIAGNOSIS:
SEROUS ADENOCARCINOMA, FIGO GRADE 2, INVOLVING
A. RIGHT GUTTER
B. LESSER SAC
C. LEFT GUTTER
D. LEFT FALLOPIAN TUBE
LEFT OVARY
E. RIGHT OVARY
RIGHT FALLOPIAN TUBE
F. UTERUS, 60 GRAMS
ENDOMETRIUM: ATROPHY
MYOMETRIUM: ADENOMYOSIS
CERVIX: NO PATHOLOGIC DIAGNOSIS.
SEROVA: EXTENSIVELY INVOLVED WITH TUMOR.
G. CUL DE SAC PERITONEUM
H. SEGMENT OF COLON
I. COLON OMENTUM
J. RIGHT DIAPHRAGM
K. SMALL BOWEL NODULE
L. SEROSA OF APPENDIX
M. PORTA HEPATIC

NOTE: The tumor is massive and extensively involves every specimen submitted

[page 3 of 3]
for microscopic examination. The site of origin is uncertain based on the pathology alone. Both ovaries are small but the parenchyma is focally involved with tumor. The left ovary is the suspected primary both because the tumor has a serous appearance, and also because there are small nodules of tumor within the parenchyma. However, an equally plausible primary is from the peritoneum itself, because of the massive nature of the tumor and the relative paucity of ovarian involvement.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

DIAGNOSIS:
SEE REVISED REPORT

TCGA-29-1710

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 6e341c22-c8ad-4109-95a9-1146d91e67b3 (TCGA-29-1710.52A0D2AE-7467-40F0-B8F3-59812CFAC52A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).